Gene-level copy-number profile of tumor specimen TCGA-VG-A8LO-01A from TCGA case TCGA-VG-A8LO, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: GB; Age at diagnosis: 55.5 years (20,274 days).
Specimen TCGA-VG-A8LO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.254728bc-a38b-4133-8995-663648738957.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VG-A8LO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d0949a24-45da-43ae-904e-dee1e75a910d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 14,024; copy number 2: 37,440; copy number 3: 4,654; copy number 4: 2,782; copy number 5: 905; copy number 6: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VG-A8LO-01A-11D-A402-01): tumor purity 0.93, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:80,034,346–80,247,514, 9 genes: AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 906 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:191,952,349–198,222,513, 187 genes, copy number 5 (broad region; genes not listed).
- chr8:62,110,524–63,589,408, 22 genes, copy number 5: NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1.
- chr8:103,016,744–104,256,094, 27 genes, copy number 5 (within-gene range 4–5): NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1.
- chr8:105,826,570–144,143,664, 519 genes, copy number 5 (broad region; genes not listed).
- chr11:85,957,175–86,423,109, 12 genes, copy number 5 (within-gene range 4–5): PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81.
- chr11:86,432,098–86,437,282, 2 genes, copy number 5: PTP4A1P6, AP001148.1.
- chr11:97,086,160–97,086,682, 1 gene, copy number 5: AP001836.1.
- chr11:118,747,763–121,453,013, 89 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:131,370,478–132,336,822, 1 gene, copy number 5 (within-gene range 4–5): NTM.
- chr11:131,770,795–135,075,908, 45 genes, copy number 5: AP004372.1, AP000844.2, AP000844.1, NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr20:12,865,202–12,952,519, 1 gene, copy number 6 (within-gene range 3–6): LINC01722.

Autosomal genes at a single copy (total copy number 1): 12,939. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
